Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7300, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7300-01A (Primary Tumor).

[page 1 of 3]
=====

CLINICAL HISTORY

Not Given

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Right frontal tumor, Brain, resection

B: Right frontal tumor (permanent), Brain, resection

PATHOLOGICAL DIAGNOSIS:

A and B Brain, right frontal, biopsy: Anaplastic oligodendroglioma,
MIB-1:

25 30%

COMMENT

This is an oligodendroglioma with focal areas of hypercellularity and moderate nuclear pleomorphism. There is increased mitotic figure in some fragments

There is no vascular hyperplasia nor tumor necrosis. Astrocytoma component is no present.

=====

Interpretation

POSITIVE - Methylated MGMT promoter is detected.

Results-Comments

[page 2 of 3]
[REDACTED] Submitted, paraffin curls labeled [REDACTED] (B3) dated [REDACTED]

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

Right frontal tumor, Brain, resection: Glioma, 1 block, (KH)

[REDACTED]

GROSS DESCRIPTION

- A. multiple tissue fragments, 0.2 to 0.4 cm, all in A1, A2
- B. Multiple tissue fragments, 1.5 to 2.0 cm, all in B1 to B3
- [REDACTED]

ICD-9(s):

191.1 191.1 191.1 191.1

[REDACTED]

Histo Data

Part A: Right frontal tumor, Brain, resection

Taken: [REDACTED]

Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	

Part B: Right frontal tumor (permanent), Brain, resection

[page 3 of 3]
Taken:

Stain/chr	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		
mGFAP-DA x 1	3		
H/E x 1	3		
MIB1-DA x 1	3		

*** End of Report ***

Source: NCI Genomic Data Commons file 23684165-a55d-4404-bf97-db87e3486846 (TCGA-DU-7300.6A6A701F-4276-4EE8-9D47-9DD470F1F3EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).